Somatic mutation profile of tumor specimen MP2PRT-PAUTYR-TMP1-A (aliquot MP2PRT-PAUTYR-TMP1-A-2-0-D-A79Q-36) from MP2PRT case MP2PRT-PAUTYR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 7.0 years (2,551 days).
Specimen MP2PRT-PAUTYR-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3305514-9cd4-4a01-81de-33aec3b84692.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUTYR-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUTYR-NB1-A-1-0-D-A79Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eeb3ff41-6801-4474-be39-ecf876d98a56

The open-access MAF lists 52 somatic variants for this specimen: 40 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 29, Silent 12, Nonsense Mutation 4, Frame Shift Ins 3, Frame Shift Del 2, In Frame Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASRGL1 | c.728C>T p.T243M | Missense Mutation (SNP) | VAF 55/237 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs149064193; called by muse, mutect2, varscan2
- BCOR | c.4405C>T p.R1469W (on ENST00000378444 / NM_001123385.2; = p.R1435W on NM_017745.6) | Missense Mutation (SNP) | VAF 135/335 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1356916187, COSV60716562; called by muse, mutect2, varscan2
- CDH9 | c.655A>G p.T219A | Missense Mutation (SNP) | VAF 59/226 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV99146455; called by muse, mutect2, varscan2
- ESR1 | c.1664G>A p.R555H | Missense Mutation (SNP) | VAF 74/388 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs778554662, CM1212985, COSV52786790; called by muse, mutect2, varscan2
- KCTD5 | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 110/126 reads (87%) | catalogued as rs756594781, COSV57064149; called by muse, mutect2, varscan2
- MAGI1 | c.3706C>T p.R1236C | Missense Mutation (SNP) | VAF 141/562 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); catalogued as rs768709936, COSV100441314; called by muse, mutect2, varscan2
- MARCHF10 | c.103C>T p.R35* | Nonsense Mutation (SNP) | VAF 50/204 reads (25%) | catalogued as rs200814272, COSV60888723; called by muse, varscan2
- MOXD1 | c.947G>A p.G316D | Missense Mutation (SNP) | VAF 31/169 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.823); catalogued as rs1450669678; called by muse, mutect2, varscan2
- MTHFD1L | c.2546C>T p.A849V | Missense Mutation (SNP) | VAF 59/259 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.85); catalogued as rs35829704; called by muse, mutect2, varscan2
- MYO1E | c.2440C>T p.R814W | Missense Mutation (SNP) | VAF 197/383 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746567114; called by muse, mutect2, varscan2
- NFKBIZ | c.376C>T p.H126Y | Missense Mutation (SNP) | VAF 91/355 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.714); catalogued as rs781316486; called by muse, mutect2, varscan2
- PLA2R1 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 101/380 reads (27%) | PolyPhen benign (0); catalogued as rs1272138086; called by muse, varscan2
- PLEC | c.12248G>A p.R4083Q (on ENST00000322810 / NM_201380.4; = p.R3973Q on NM_000445.5) | Missense Mutation (SNP) | VAF 13/317 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as rs782131159, COSV59650678; called by muse, mutect2
- PNLIP | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 83/346 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.884); catalogued as rs778815857, COSV65040591; called by muse, mutect2, varscan2
- REM2 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 94/381 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as rs894910280, COSV57465432; called by muse, mutect2, varscan2
- RHPN2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 140/358 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.168); catalogued as rs1284726121; called by muse, varscan2
- SH2B3 | c.1244G>C p.R415P | Missense Mutation (SNP) | VAF 46/216 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57981694; called by mutect2, varscan2
- SH2B3 | c.1566dup p.E523Rfs*23 | Frame Shift Ins (INS) | VAF 194/356 reads (54%) | catalogued as rs751076276; called by mutect2, varscan2
- SH3BP4 | c.2638C>T p.R880W | Missense Mutation (SNP) | VAF 23/422 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs967693267; called by muse, mutect2
- VWCE | c.395C>T p.T132M | Missense Mutation (SNP) | VAF 132/324 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.138); catalogued as rs1468265362; called by muse, mutect2, varscan2
- ADAMTS9 | c.2317C>G p.P773A | Missense Mutation (SNP) | VAF 122/288 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ALKBH5 | c.430C>A p.Q144K | Missense Mutation (SNP) | VAF 98/459 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- ASXL2 | c.1415_1416del p.H472Rfs*3 | Frame Shift Del (DEL) | VAF 72/338 reads (21%) | called by mutect2, varscan2
- CIB2 | c.27_28insCCC p.T9_E10insP | In Frame Ins (INS) | VAF 90/376 reads (24%) | called by mutect2, varscan2
- FLG | c.7103C>G p.A2368G | Missense Mutation (SNP) | VAF 82/360 reads (23%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- HMGB1 | c.329_330insGGGACCG p.P111Gfs*16 | Frame Shift Ins (INS) | VAF 52/175 reads (30%) | called by mutect2, varscan2
- KAT6B | c.3170_3171insTTA p.E1057delinsD* | Nonsense Mutation (INS) | VAF 86/364 reads (24%) | called by mutect2, varscan2
- KAT6B | c.3172del p.R1058Efs*56 | Frame Shift Del (DEL) | VAF 88/365 reads (24%) | called by mutect2, varscan2
- KCNC3 | c.778G>T p.G260C | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- NEXMIF | c.4355C>A p.S1452Y | Missense Mutation (SNP) | VAF 81/395 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- OGT | c.1349C>T p.A450V | Missense Mutation (SNP) | VAF 65/282 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- PGPEP1 | c.41G>A p.G14D | Missense Mutation (SNP) | VAF 89/410 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- RCBTB1 | c.462T>G p.Y154* | Nonsense Mutation (SNP) | VAF 69/293 reads (24%) | called by muse, mutect2, varscan2
- RPS6KA6 | c.704G>A p.G235D | Missense Mutation (SNP) | VAF 86/395 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SEL1L2 | c.106A>G p.T36A | Missense Mutation (SNP) | VAF 43/222 reads (19%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SH2B3 | c.1243_1244insCC p.R415Pfs*5 | Frame Shift Ins (INS) | VAF 43/213 reads (20%) | called by mutect2, varscan2
- TEK | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- THBS4 | c.1444T>A p.C482S | Missense Mutation (SNP) | VAF 63/288 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- UXS1 | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 132/317 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ZNF804B | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 83/205 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- C20orf141 | c.402G>A p.L134= | Silent (SNP) | VAF 200/425 reads (47%) | called by muse, varscan2
- EPHB3 | c.2643C>T p.L881= | Silent (SNP) | VAF 126/525 reads (24%) | catalogued as rs746453403, COSV57808594; called by muse, mutect2, varscan2
- GPD1 | c.513G>A p.P171= | Silent (SNP) | VAF 136/286 reads (48%) | catalogued as rs753210151; called by muse, mutect2, varscan2
- HTR5A | c.117C>T p.F39= | Silent (SNP) | VAF 120/499 reads (24%) | catalogued as rs267601433, COSV99839436; called by muse, mutect2, varscan2
- IDS | c.492G>A p.K164= | Silent (SNP) | VAF 116/311 reads (37%) | called by muse, mutect2, varscan2
- NUPR1 | c.99C>T p.A33= | Silent (SNP) | VAF 10/284 reads (4%) | called by muse, mutect2
- NYAP2 | c.1029C>T p.P343= | Silent (SNP) | VAF 131/298 reads (44%) | catalogued as rs1559221187, COSV56016389; called by muse, mutect2, varscan2
- PEX7 | c.21A>G p.G7= | Silent (SNP) | VAF 21/484 reads (4%) | called by muse, mutect2
- SFTPA1 | c.375C>T p.L125= | Silent (SNP) | VAF 106/352 reads (30%) | catalogued as COSV64866990; called by muse, mutect2, varscan2
- SLC5A11 | c.408C>T p.F136= | Silent (SNP) | VAF 70/338 reads (21%) | catalogued as rs776483702, COSV61740993; called by muse, mutect2, varscan2
- WNT5A | c.603G>A p.E201= | Silent (SNP) | VAF 23/642 reads (4%) | called by muse, mutect2
- ZNF483 | c.1860G>A p.T620= | Silent (SNP) | VAF 80/361 reads (22%) | catalogued as rs142830150; called by muse, mutect2, varscan2
